TCGA case TCGA-XF-A9SW — Bladder Urothelial Carcinoma (TCGA-BLCA)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Transitional Cell Papillomas and Carcinomas; Primary site: Bladder; Tissue source site: University of Southern California. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f5e03536-26e1-480d-a7bb-010eb8210cd6

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 85 years; Vital status: Dead; Days to death: 362 days.

Diagnoses (5)
1. Transitional cell carcinoma (the primary disease): ICD-O-3 morphology code: 8120/3; ICD-10 code: C67.9; Tissue or organ of origin: Bladder, NOS; Site of resection or biopsy: Bladder, NOS; Classification of tumor: primary; Age at diagnosis: 85.0 years (31,049 days); Year of diagnosis: 2006; Method of diagnosis: Surgical Resection; AJCC staging edition: 6th; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Prior malignancy: yes; Synchronous malignancy: Yes; Prior treatment: No.
   Pathology details: Consistent pathology review: Yes; Extracapsular extension present: No; Lymph nodes positive: 4; Lymph nodes tested: 19; Lymphatic invasion present: Yes; Vascular invasion present: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Papillary transitional cell carcinoma: ICD-O-3 morphology code: 8130/3; Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary; Age at diagnosis: 84.6 years (30,901 days); Days to diagnosis: -148 days; AJCC pathologic T: Ta.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: -148 days; Treatment anatomic sites: Bladder.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Papillary transitional cell carcinoma, non-invasive: Tissue or organ of origin: Bladder, NOS; Classification of tumor: Prior primary.
   Treatment given: Treatment type: Surgery, NOS; Timepoint category: Prior to Procurement.
4. Carcinoma, NOS: Tissue or organ of origin: Prostate gland; Classification of tumor: Synchronous primary; AJCC pathologic T: T3a.
5. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Prostate gland; Laterality: Bilateral; Classification of tumor: Synchronous primary; Age at diagnosis: 85.1 years (31,089 days); Days to diagnosis: 40 days; AJCC staging edition: 4th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 40 days; Treatment anatomic sites: Prostate.
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 362 days; Disease response: With Tumor.
- Karnofsky performance status: 90.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg; Height: 179 cm; BMI: 20.3.

Exposures
- Occupation type: Process Control Technicians.
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Tobacco smoking quit year: 1965.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Pancreas Cancer.
- Relative with cancer history: yes; Relationship type: Child; Relationship primary diagnosis: Breast Cancer.
- Relative with cancer history: yes; Relationship type: Father; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Lung Cancer.
- Relative with cancer history: yes; Relationship type: Brother; Relationship primary diagnosis: Prostate Cancer.
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-XF-A9SW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 480 mg.
  Slide TCGA-XF-A9SW-01A-01-TSA: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 2; Percent neutrophil infiltration: 5.
- Sample TCGA-XF-A9SW-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-XF-A9SW-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Occupation current: Retired; Occupation primary: Gas Company; Tobacco smoking history indicator: 3; Histologic diagnosis: Muscle invasive urothelial carcinoma (pT2 or above); Histologic subtype: Non-Papillary; Anatomic organ subdivision: Bladder - NOS; Method initial path diagnosis: Transurethral resection (TURBT); Lymph nodes examined: Yes; Lymphovascular invasion: Yes; Incidental prostate cancer indicator: Yes; AJCC path pathologic T incidental prostate: pT3a; Treatment outcome first course: Partial Remission/Response; New tumor event diagnosis indicator: No.
- Stage record, Gleason grading: Gleason score: 7.
- History non muscle invasive blca: Noninvasive bladder history: Yes; Noninvasive bladder CA treatment type: Transurethral resection alone.
- Other malignancy form 1: Malignancy type: Synchronous Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: Adenocarcinoma, Not Otherwise Specified.
- Other malignancy form 1, Surgery: Other malignancy surgery type: Prostatectomy.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy histological type: papillary urothelial carcinoma.
- Other malignancy form 2, Surgery: Other malignancy surgery type: Turbt.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 362 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 362 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 362 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-XF-A9SW-01A-11D-A42D-01): tumor purity 0.34, ploidy 1.76, whole-genome doublings 0.
